Somatic mutation profile of tumor specimen 0DUFEA from CCDI case PBCKXM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.8 years (3,936 days).
Specimen 0DUFEA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58b2899e-d6b6-47e9-a142-5a16495e2d2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUFDB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcccf35c-4049-48f2-8687-97d6c794d46a

The open-access MAF lists 8 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NXPH2 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 15/478 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55640291; called by muse, mutect2
- SPIN2A | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 36/675 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs767177597; called by muse, mutect2
- EXO1 | c.1467G>A p.R489= | Silent (SNP) | VAF 27/458 reads (6%) | called by muse, mutect2
- FAM47A | c.990G>A p.P330= | Silent (SNP) | VAF 52/352 reads (15%) | catalogued as rs753788971, COSV60499032; called by mutect2, varscan2
- MBOAT7 | c.216C>T p.H72= | Silent (SNP) | VAF 68/476 reads (14%) | catalogued as rs752885443, COSV55476421; called by muse, mutect2, varscan2
- DIP2C | c.*8_*51del | 3'UTR (DEL) | VAF 43/273 reads (16%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.12684+82T>G | Intron (SNP) | VAF 16/225 reads (7%) | catalogued as rs1328249555; called by muse, mutect2
- P4HTM | c.887+51G>A | Intron (SNP) | VAF 14/291 reads (5%) | called by muse, mutect2
